Somatic mutation profile of tumor specimen TCGA-G9-6342-01A (aliquot TCGA-G9-6342-01A-11D-1961-08) from TCGA case TCGA-G9-6342, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.5 years (22,472 days).
Specimen TCGA-G9-6342-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea0fe684-f2c6-4d77-b33f-0f3650ebc02f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6342-10A (Blood Derived Normal), aliquot TCGA-G9-6342-10A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/358a5595-81aa-49dd-9f47-1e5577a9d3e1

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 15, Silent 6, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB3 | c.3340A>T p.M1114L | Missense Mutation (SNP) | VAF 47/242 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV53256837; called by muse, mutect2, varscan2
- ADGRG4 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 53/91 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs142877839, COSV54962720, COSV54964266; called by muse, mutect2, varscan2
- ASTN1 | c.2269G>A p.G757S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV56071993; called by muse, mutect2, varscan2
- BAZ2B | c.5744G>A p.C1915Y | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58607838; called by muse, mutect2
- BEST3 | c.33T>A p.N11K | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as COSV56995665; called by muse, mutect2, varscan2
- C9 | c.1111+1G>A p.X371_splice | Splice Site (SNP) | VAF 16/65 reads (25%) | catalogued as COSV54680280; called by muse, mutect2, varscan2
- DUS3L | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.209); catalogued as COSV57833239; called by muse, mutect2, varscan2
- GPS2 | c.430C>G p.L144V | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV59752594; called by muse, mutect2, varscan2
- ICAM5 | c.1610A>C p.E537A | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.171); catalogued as COSV55748779; called by muse, mutect2, varscan2
- KAT5 | c.1084A>G p.T362A | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.206); catalogued as COSV57730424; called by muse, mutect2, varscan2
- METTL7A | c.106T>C p.F36L | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs754114056, COSV59841205; called by muse, mutect2, varscan2
- PAK2 | c.53T>A p.M18K | Missense Mutation (SNP) | VAF 12/247 reads (5%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.028); catalogued as COSV59084510; called by muse, mutect2
- PREX2 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs200682883, COSV55757236, COSV55764910; called by mutect2, varscan2
- UGT2B17 | c.1193C>G p.A398G | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as COSV58501973, COSV58502387; called by muse, mutect2, varscan2
- XPO6 | c.2872G>A p.V958M | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV100484907, COSV58964930; called by muse, mutect2, varscan2
- ZNF518B | c.2233T>C p.Y745H | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.365); catalogued as rs929294954, COSV58724330; called by muse, mutect2, varscan2
- DSTYK | c.1473C>T p.F491= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs775721917, COSV65688091; called by muse, mutect2, varscan2
- HMCN1 | c.1956C>T p.I652= | Silent (SNP) | VAF 23/131 reads (18%) | catalogued as rs766591582, COSV54931151; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HSPBAP1 | c.1104C>T p.G368= | Silent (SNP) | VAF 30/386 reads (8%) | catalogued as COSV60243464; called by muse, mutect2
- INTU | c.1659A>G p.K553= | Silent (SNP) | VAF 26/158 reads (16%) | catalogued as COSV58873980; called by muse, mutect2, varscan2
- KCNT2 | c.2640G>A p.L880= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV54102211; called by muse, mutect2, varscan2
- PDZD4 | c.156C>T p.R52= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV51249867; called by mutect2, varscan2
